Somatic mutation profile of cancer-model specimen HCM-BROD-0555-C15-85M (3D Organoid, passage 4; aliquot HCM-BROD-0555-C15-85M-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0555-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 48.2 years (17,601 days).
Specimen HCM-BROD-0555-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f8f53f7-9115-4a1a-ae9e-96dae9a72825.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0555-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0555-C15-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6d3fbfb-c0c5-47f1-9f8f-e228fee83b80

The open-access MAF lists 216 somatic variants for this specimen: 169 protein-altering or splice-affecting, 43 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 43, Nonsense Mutation 20, Frame Shift Ins 3, 3'UTR 2, In Frame Del 2, Frame Shift Del 2, Intron 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 253/253 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.061); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- ADAMTS6 | c.1155G>T p.R385S | Missense Mutation (SNP) | VAF 305/306 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101124555, COSV66862833; called by muse, mutect2, varscan2
- ANKRD12 | c.2414A>G p.E805G | Missense Mutation (SNP) | VAF 276/289 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as COSV50822314; called by muse, mutect2, varscan2
- APBA2 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 312/605 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV68794610; called by muse, mutect2, varscan2
- BRINP1 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV56309272; called by muse, mutect2, varscan2
- C19orf85 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 155/744 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1440437025; called by muse, mutect2, varscan2
- CCDC121 | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 24/582 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV53118197; called by muse, mutect2
- CDH10 | c.807C>A p.F269L | Missense Mutation (SNP) | VAF 62/441 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100051552, COSV52568750; called by muse, mutect2, varscan2
- CDH6 | c.1609T>G p.F537V | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV54074174; called by muse, mutect2, varscan2
- CELSR2 | c.4881G>C p.W1627C | Missense Mutation (SNP) | VAF 173/362 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54779790, COSV99603812; called by muse, mutect2, varscan2
- CSNK1A1L | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65789528; called by muse, mutect2, varscan2
- CYBA | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 35/570 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs909600062; called by muse, mutect2
- CYP2A13 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 144/515 reads (28%) | catalogued as rs201720562; called by muse, mutect2, varscan2
- DOK5 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200557118, COSV52825434; called by muse, mutect2, varscan2
- EIF2AK1 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 115/500 reads (23%) | catalogued as COSV99551901; called by muse, mutect2, varscan2
- ESPL1 | c.6136G>A p.V2046M | Missense Mutation (SNP) | VAF 112/379 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs912227150, COSV54475343; called by muse, mutect2, varscan2
- FAM171B | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 246/386 reads (64%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs779066655, COSV59001734; called by muse, mutect2, varscan2
- FBXW7 | c.1697G>T p.W566L (on ENST00000281708 / NM_001349798.2; = p.W486L on NM_018315.5) | Missense Mutation (SNP) | VAF 133/230 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949515, COSV99662097; called by muse, mutect2, varscan2
- FLRT2 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58150869; called by muse, mutect2, varscan2
- FRMPD3 | c.2348C>A p.P783H | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752491692, COSV52186708, COSV52196703; called by muse, mutect2
- GOLGA2 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 127/413 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.063); catalogued as rs748293881, COSV100360351; called by muse, mutect2, varscan2
- H2AC1 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 133/292 reads (46%) | catalogued as COSV51236684; called by muse, mutect2, varscan2
- H2AC17 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.954); catalogued as rs748960551; called by muse, mutect2, varscan2
- HLA-G | c.977C>A p.A326E | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as rs768731691, COSV64405068, COSV64406211; called by muse, mutect2
- HSDL1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 185/356 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs780457031, COSV54740518; called by muse, mutect2, varscan2
- IFI16 | c.1277T>G p.L426R | Missense Mutation (SNP) | VAF 89/321 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.795); catalogued as COSV55531820; called by muse, mutect2, varscan2
- IFT22 | c.411G>A p.S137= | Splice Region (SNP) | VAF 114/928 reads (12%) | catalogued as rs758284945; called by muse, mutect2, varscan2
- IL5RA | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 162/162 reads (100%) | catalogued as COSV56522025; called by muse, mutect2, varscan2
- INTS13 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 58/1677 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV53901016; called by muse, mutect2
- MAB21L1 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 131/441 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV100083969; called by muse, mutect2, varscan2
- MTMR6 | c.1398G>C p.K466N | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV67809021; called by muse, mutect2, varscan2
- MUC16 | c.17183C>A p.S5728Y | Missense Mutation (SNP) | VAF 98/480 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.957); catalogued as COSV67444191, COSV67500083; called by muse, mutect2, varscan2
- MYO6 | c.2515G>C p.G839R | Missense Mutation (SNP) | VAF 150/151 reads (99%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV64119369; called by muse, mutect2, varscan2
- MYT1 | c.3214G>A p.A1072T | Missense Mutation (SNP) | VAF 493/493 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs751357845, COSV60513677; called by muse, mutect2, varscan2
- NBPF1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 126/955 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747064434, COSV67431921; called by muse, mutect2, varscan2
- NLRP9 | c.2823C>A p.D941E | Missense Mutation (SNP) | VAF 133/431 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV60463787; called by muse, mutect2, varscan2
- NRP2 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 277/411 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs372080377; called by muse, mutect2, varscan2
- NRXN3 | c.1855C>T p.R619C (on ENST00000335750 / NM_001330195.2; = p.R246C on NM_004796.6) | Missense Mutation (SNP) | VAF 401/402 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764624479, COSV59714381; called by muse, mutect2, varscan2
- PACRG | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 130/255 reads (51%) | catalogued as rs376828813, COSV61301828; called by muse, mutect2, varscan2
- PCDHB1 | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60631507; called by muse, mutect2
- PCOLCE | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 1120/1457 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99575138; called by muse, mutect2, varscan2
- PDZK1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 168/505 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs782100892, COSV61091924, COSV61092455; called by muse, mutect2, varscan2
- PFDN4 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 65/147 reads (44%) | catalogued as rs773903753, COSV101004615, COSV65063404; called by muse, mutect2, varscan2
- PHF3 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 75/150 reads (50%) | catalogued as rs1340251783, COSV50328702; called by muse, mutect2, varscan2
- PRKD1 | c.2662A>G p.S888G | Missense Mutation (SNP) | VAF 162/328 reads (49%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.021); catalogued as COSV100121560, COSV59578586; called by muse, mutect2, varscan2
- PRSS1 | c.436A>G p.N146D | Missense Mutation (SNP) | VAF 120/296 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as COSV61191556; called by muse, varscan2
- PTPN12 | c.1982C>G p.S661* | Nonsense Mutation (SNP) | VAF 72/348 reads (21%) | catalogued as COSV50361777; called by muse, mutect2, varscan2
- PTPRK | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 62/490 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV63893010; called by muse, mutect2, varscan2
- RBM12B | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 390/1365 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs753811700; called by muse, mutect2, varscan2
- RGS3 | c.3533G>A p.R1178H (on ENST00000350696 / NM_001282923.2; = p.R897H on NM_130795.4) | Missense Mutation (SNP) | VAF 146/296 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59518111; called by muse, varscan2
- SETD1B | c.4630G>A p.A1544T | Missense Mutation (SNP) | VAF 255/832 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as rs868306191, COSV57351973; called by muse, mutect2, varscan2
- SMARCA2 | c.2815C>A p.H939N | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM122557; called by muse, mutect2, varscan2
- SORCS2 | c.561C>A p.F187L | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV61183382; called by muse, mutect2, varscan2
- THSD7B | c.3701A>C p.K1234T (on ENST00000272643; = p.K1232T on NM_001316349.2) | Missense Mutation (SNP) | VAF 15/335 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs1360239886, COSV55662801; called by muse, mutect2
- TMEM132D | c.2594A>C p.K865T | Missense Mutation (SNP) | VAF 157/501 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101242707, COSV67158649; called by muse, mutect2, varscan2
- TTC21A | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs761168378; called by muse, varscan2
- UROS | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 146/450 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as rs201139760; called by muse, varscan2
- VCAN | c.7256C>A p.P2419Q | Missense Mutation (SNP) | VAF 218/358 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV99426876; called by muse, mutect2, varscan2
- ZFP57 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 88/206 reads (43%) | catalogued as COSV65306795; called by muse, mutect2, varscan2
- ZNF587B | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 129/464 reads (28%) | catalogued as COSV100332126; called by muse, mutect2, varscan2
- ABCG4 | c.92del p.P31Lfs*3 | Frame Shift Del (DEL) | VAF 334/874 reads (38%) | called by mutect2, pindel, varscan2
- ABLIM3 | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 17/540 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM32 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 79/256 reads (31%) | called by mutect2, varscan2
- ALG10B | c.218T>G p.V73G | Missense Mutation (SNP) | VAF 115/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ALKBH7 | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 110/527 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ANTXR1 | c.1165G>T p.G389* | Nonsense Mutation (SNP) | VAF 65/258 reads (25%) | called by muse, mutect2
- B4GALT5 | c.1066C>A p.L356I | Missense Mutation (SNP) | VAF 60/370 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CAMTA1 | c.2522G>T p.S841I | Missense Mutation (SNP) | VAF 227/456 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CAPRIN1 | c.1321G>C p.G441R | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CCDC142 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 46/1034 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); called by muse, mutect2
- CD33 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 152/585 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- CDH8 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CEP295 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CES5A | c.69_77del p.W23_L25del | In Frame Del (DEL) | VAF 39/145 reads (27%) | called by mutect2, pindel, varscan2
- CKAP5 | c.985G>T p.G329* | Nonsense Mutation (SNP) | VAF 76/285 reads (27%) | called by muse, mutect2, varscan2
- COL6A3 | c.4401C>A p.N1467K | Missense Mutation (SNP) | VAF 349/522 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DACH2 | c.1573dup p.T525Nfs*12 | Frame Shift Ins (INS) | VAF 120/246 reads (49%) | called by mutect2, varscan2
- DCSTAMP | c.85T>G p.F29V | Missense Mutation (SNP) | VAF 283/721 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDIAS | c.1076C>A p.A359E | Missense Mutation (SNP) | VAF 158/370 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- DDX1 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMXL1 | c.1229dup p.L410Ffs*5 | Frame Shift Ins (INS) | VAF 76/273 reads (28%) | called by mutect2, varscan2
- DTX2 | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 94/996 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- E2F8 | c.1547C>A p.P516H | Missense Mutation (SNP) | VAF 108/604 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); called by mutect2, varscan2
- EFCAB6 | c.2029C>A p.L677M | Missense Mutation (SNP) | VAF 122/253 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EPB42 | c.673C>A p.Q225K (on ENST00000441366 / NM_001114134.2; = p.Q255K on NM_000119.3) | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- EPRS1 | c.3313A>G p.T1105A | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXL13 | c.1546G>T p.E516* | Nonsense Mutation (SNP) | VAF 52/1094 reads (5%) | called by muse, mutect2
- FIG4 | c.2273C>A p.S758Y | Missense Mutation (SNP) | VAF 135/274 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FOLR2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 109/487 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FOXI1 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 23/777 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2
- FSCB | c.1319T>C p.L440P | Missense Mutation (SNP) | VAF 26/425 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- FSIP2 | c.17570G>T p.G5857V | Missense Mutation (SNP) | VAF 118/411 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- GATAD2B | c.277G>T p.G93* | Nonsense Mutation (SNP) | VAF 174/530 reads (33%) | called by muse, mutect2, varscan2
- GOLGA6L22 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 96/271 reads (35%) | called by muse, mutect2, varscan2
- GOLT1B | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 52/2138 reads (2%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GRAMD2A | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.654); called by mutect2, varscan2
- GRXCR2 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 142/458 reads (31%) | called by muse, mutect2, varscan2
- H2AC11 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- H2BC9 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- HCN1 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 18/465 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- HECTD1 | c.5923G>A p.D1975N | Missense Mutation (SNP) | VAF 185/351 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HEXB | c.1337C>A p.S446Y | Missense Mutation (SNP) | VAF 22/433 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- IQCC | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.081); called by muse, mutect2
- KCNS2 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 247/656 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- LAMTOR3 | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 112/236 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- LIG4 | c.2512_2530del p.L838Sfs*9 | Frame Shift Del (DEL) | VAF 114/237 reads (48%) | called by mutect2, pindel, varscan2
- LMO7 | c.1177C>A p.P393T (on ENST00000357063; = p.P123T on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/366 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- LRP2 | c.12465T>G p.H4155Q | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYPD3 | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 17/671 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2
- MMS22L | c.3584C>A p.S1195Y | Missense Mutation (SNP) | VAF 110/231 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- MUC16 | c.34226C>A p.T11409N | Missense Mutation (SNP) | VAF 47/466 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- NEB | c.5443G>T p.A1815S | Missense Mutation (SNP) | VAF 141/252 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUP214 | c.2584G>T p.A862S | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2
- OAS2 | c.1347G>T p.E449D | Missense Mutation (SNP) | VAF 154/519 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR13C3 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); called by muse, mutect2
- OR14A16 | c.302dup p.L101Ffs*19 | Frame Shift Ins (INS) | VAF 94/355 reads (26%) | called by mutect2, pindel, varscan2
- OR4A5 | c.21T>G p.I7M | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); called by muse, mutect2
- OR6K3 | c.191C>A p.A64D (on ENST00000368146; = p.A48D on NM_001005327.2) | Missense Mutation (SNP) | VAF 129/395 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR8H2 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PGAM1 | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 164/596 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- PGBD1 | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 11/292 reads (4%) | called by muse, mutect2
- PITPNM1 | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 146/547 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PLEKHG7 | c.1967A>C p.K656T | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POU6F1 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRRC2C | c.800T>C p.M267T (on ENST00000367742; = p.M265T on NM_015172.4) | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- PRSS27 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 26/588 reads (4%) | called by muse, mutect2
- PTPN7 | c.166G>A p.G56R (on ENST00000495688; = p.G95R on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/427 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PTPRC | c.3062C>G p.S1021C | Missense Mutation (SNP) | VAF 154/247 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRQ | c.1615G>A p.D539N (on ENST00000616559; = p.D497N on NM_001145026.2) | Missense Mutation (SNP) | VAF 120/331 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIC8A | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 182/765 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- RICTOR | c.2330C>G p.A777G | Missense Mutation (SNP) | VAF 204/306 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RP1L1 | c.599G>T p.S200I | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SH3D19 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- SIRPG | c.1048C>A p.H350N | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SPATA31D1 | c.965A>T p.K322M | Missense Mutation (SNP) | VAF 442/443 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- SPTA1 | c.1593G>T p.K531N | Missense Mutation (SNP) | VAF 89/261 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTBN5 | c.7643G>T p.R2548L | Missense Mutation (SNP) | VAF 365/366 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SRPK2 | c.45_71+5del p.X15_splice | Splice Site (DEL) | VAF 32/386 reads (8%) | called by mutect2, pindel
- SRRD | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STAG1 | c.3504G>T p.K1168N | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- STKLD1 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- STX11 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 406/406 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SYMPK | c.357G>T p.R119S | Missense Mutation (SNP) | VAF 97/444 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SYNDIG1 | c.427A>C p.I143L | Missense Mutation (SNP) | VAF 146/429 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TEX47 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 102/1732 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- TMEM203 | c.337_345delinsATTACG p.W113_G115delinsIT | In Frame Del (DEL) | VAF 224/429 reads (52%) | called by pindel, varscan2*
- TNNT2 | c.742C>A p.Q248K (on ENST00000236918; = p.Q245K on NM_000364.4) | Missense Mutation (SNP) | VAF 122/416 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TPTE | c.545A>C p.K182T (on ENST00000618007 / NM_199261.4; = p.K164T on NM_199259.4) | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TRIM49 | c.982T>C p.F328L | Missense Mutation (SNP) | VAF 96/688 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- TRPC5 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TSPYL6 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 96/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TTN | c.69692G>T p.R23231I (on ENST00000591111; = p.R15807I on NM_003319.4) | Missense Mutation (SNP) | VAF 277/437 reads (63%) | PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TYRO3 | c.2590G>C p.E864Q | Missense Mutation (SNP) | VAF 309/310 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- U2AF2 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 123/476 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- UBN2 | c.3532C>A p.L1178I | Missense Mutation (SNP) | VAF 141/286 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- URB1 | c.3767G>T p.G1256V | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- USP42 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 189/844 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VANGL1 | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 137/313 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VAX2 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 131/413 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VPS35 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- VPS37A | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2
- ZBTB37 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 110/351 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ZDHHC12 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 209/738 reads (28%) | called by muse, mutect2, varscan2
- ZNF181 | c.244T>C p.W82R | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF433 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ZNF585A | c.452T>G p.V151G (on ENST00000292841 / NM_001288800.2; = p.V96G on NM_152655.3) | Missense Mutation (SNP) | VAF 107/581 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ZNF670 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF682 | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ZNF85 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACVR2A | c.543C>A p.P181= | Silent (SNP) | VAF 192/306 reads (63%) | called by muse, mutect2, varscan2
- AGPAT5 | c.99G>T p.G33= | Silent (SNP) | VAF 229/453 reads (51%) | called by muse, mutect2, varscan2
- BAZ2A | c.4696C>A p.R1566= | Silent (SNP) | VAF 204/549 reads (37%) | catalogued as rs1328077812; called by muse, mutect2, varscan2
- C4orf47 | c.375C>T p.S125= | Silent (SNP) | VAF 272/272 reads (100%) | catalogued as rs753432654, COSV66631414; called by muse, mutect2, varscan2
- CACNA1F | c.3564C>T p.N1188= | Silent (SNP) | VAF 22/476 reads (5%) | called by muse, mutect2
- CADM1 | c.390C>T p.P130= | Silent (SNP) | VAF 178/406 reads (44%) | catalogued as rs1423385858; called by muse, mutect2, varscan2
- CDC42BPA | c.3078T>C p.C1026= (on ENST00000334218 / NM_001366019.2; = p.C1013= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/348 reads (29%) | called by muse, mutect2, varscan2
- CEP250 | c.555G>C p.V185= | Silent (SNP) | VAF 42/609 reads (7%) | called by muse, mutect2
- CEP350 | c.4482C>A p.T1494= | Silent (SNP) | VAF 78/309 reads (25%) | called by muse, mutect2, varscan2
- CNTLN | c.3907A>C p.R1303= | Silent (SNP) | VAF 100/231 reads (43%) | catalogued as COSV52086476; called by muse, mutect2, varscan2
- COL5A1 | c.1140C>T p.T380= | Silent (SNP) | VAF 228/385 reads (59%) | catalogued as rs749315207; ClinVar: likely benign; called by muse, mutect2, varscan2
- DBX1 | c.795C>T p.L265= | Silent (SNP) | VAF 163/863 reads (19%) | catalogued as rs140374117; called by muse, mutect2, varscan2
- DCLK1 | c.1521C>T p.I507= | Silent (SNP) | VAF 124/411 reads (30%) | catalogued as rs749378165, COSV55184871; called by muse, mutect2, varscan2
- DEFB124 | c.108T>G p.T36= | Silent (SNP) | VAF 337/529 reads (64%) | catalogued as COSV58343742; called by muse, mutect2, varscan2
- DUSP23 | c.303C>A p.R101= | Silent (SNP) | VAF 122/378 reads (32%) | called by muse, mutect2, varscan2
- EN2 | c.807G>A p.L269= | Silent (SNP) | VAF 172/315 reads (55%) | called by muse, mutect2, varscan2
- FLNA | c.4986C>A p.P1662= (on ENST00000369850 / NM_001110556.2; = p.P1654= on NM_001456.3) | Silent (SNP) | VAF 86/214 reads (40%) | catalogued as COSV100774890; called by muse, mutect2, varscan2
- GPR45 | c.408C>T p.I136= | Silent (SNP) | VAF 212/565 reads (38%) | catalogued as rs770278854; called by muse, mutect2, varscan2
- HSPA5 | c.72G>A p.K24= | Silent (SNP) | VAF 191/608 reads (31%) | called by muse, mutect2, varscan2
- KCNJ12 | c.1110C>A p.P370= | Silent (SNP) | VAF 232/706 reads (33%) | called by muse, mutect2, varscan2
- KIAA1549L | c.2982T>C p.N994= (on ENST00000321505; = p.N1291= on NM_012194.3) | Silent (SNP) | VAF 176/373 reads (47%) | called by muse, mutect2, varscan2
- LACTBL1 | c.549C>T p.F183= (on ENST00000618559; = p.F228= on NM_001289974.2) | Silent (SNP) | VAF 136/289 reads (47%) | called by muse, mutect2, varscan2
- LCE1F | c.222C>A p.G74= | Silent (SNP) | VAF 175/538 reads (33%) | called by muse, varscan2
- MAP3K21 | c.387C>A p.L129= | Silent (SNP) | VAF 284/893 reads (32%) | called by muse, mutect2, varscan2
- MYO15B | c.7212C>A p.R2404= | Silent (SNP) | VAF 122/508 reads (24%) | called by muse, mutect2, varscan2
- NABP1 | c.186C>T p.I62= | Silent (SNP) | VAF 173/483 reads (36%) | catalogued as rs751064773, COSV100323066; called by muse, mutect2, varscan2
- NLRP14 | c.933T>G p.T311= | Silent (SNP) | VAF 128/435 reads (29%) | catalogued as COSV100204465; called by muse, mutect2, varscan2
- NOLC1 | c.159C>A p.I53= | Silent (SNP) | VAF 97/357 reads (27%) | called by muse, mutect2, varscan2
- OR3A1 | c.495C>A p.A165= | Silent (SNP) | VAF 196/447 reads (44%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.381C>T p.N127= | Silent (SNP) | VAF 34/339 reads (10%) | catalogued as rs145692116; called by muse, mutect2, varscan2
- RC3H2 | c.2766C>A p.V922= | Silent (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- RUNX1T1 | c.573G>T p.L191= (on ENST00000265814 / NM_001198628.1; = p.L164= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/486 reads (3%) | called by muse, mutect2
- SLC1A3 | c.993C>T p.I331= | Silent (SNP) | VAF 121/673 reads (18%) | catalogued as rs768494940, COSV54315283; called by muse, mutect2, varscan2
- SLC22A12 | c.132G>T p.V44= | Silent (SNP) | VAF 187/740 reads (25%) | catalogued as rs771483073; called by muse, mutect2, varscan2
- SYT3 | c.1221G>T p.L407= | Silent (SNP) | VAF 180/669 reads (27%) | called by muse, mutect2, varscan2
- TARBP1 | c.750C>A p.R250= | Silent (SNP) | VAF 258/679 reads (38%) | called by muse, mutect2, varscan2
- TLDC2 | c.594G>T p.L198= | Silent (SNP) | VAF 84/536 reads (16%) | called by muse, mutect2, varscan2
- ZBTB16 | c.333C>T p.I111= | Silent (SNP) | VAF 151/500 reads (30%) | catalogued as rs200027612, COSV100252118; called by muse, mutect2, varscan2
- ZFP36L2 | c.447C>A p.I149= | Silent (SNP) | VAF 456/710 reads (64%) | catalogued as rs970841950, COSV99143570; called by muse, mutect2, varscan2
- ZIC3 | c.1002C>A p.G334= | Silent (SNP) | VAF 169/355 reads (48%) | called by muse, mutect2, varscan2
- ZIM3 | c.1032T>C p.F344= | Silent (SNP) | VAF 106/485 reads (22%) | catalogued as rs770048271; called by muse, mutect2, varscan2
- ZNF579 | c.9G>T p.P3= | Silent (SNP) | VAF 114/620 reads (18%) | called by muse, mutect2, varscan2
- ZNF835 | c.954C>T p.S318= | Silent (SNP) | VAF 377/673 reads (56%) | catalogued as rs1237660184, COSV73379695; called by muse, mutect2, varscan2
- B4GALNT1 | c.712+247T>G | Intron (SNP) | VAF 46/424 reads (11%) | catalogued as rs1261691120; called by muse, mutect2, varscan2
- ITPR2 | c.525+1063C>A | Intron (SNP) | VAF 146/2755 reads (5%) | called by muse, mutect2
- KIRREL2 | c.*13G>T | 3'UTR (SNP) | VAF 97/574 reads (17%) | called by muse, mutect2, varscan2
- SPAG11B | c.*125G>T | 3'UTR (SNP) | VAF 40/648 reads (6%) | called by muse, mutect2
